Somatic mutation profile of tumor specimen 0DZIX5 from CCDI case PBCUFJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DZIX5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06116b60-089e-4560-9679-7dc732c08377.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZIXK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c40bb6f-9164-49ff-bb18-78159bc95f2d

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NUDCD1 | c.1544G>C p.R515P | Missense Mutation (SNP) | VAF 94/196 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53458610; called by muse, varscan2
- OR10G9 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66686932; called by muse, varscan2
- PLEC | c.3581C>A p.S1194* (on ENST00000322810 / NM_201380.4; = p.S1084* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 66/121 reads (55%) | catalogued as COSV59688582; called by muse, varscan2
- RAP1GAP | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs1329287230; called by muse, varscan2
- SKIL | c.29T>G p.L10W | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV52061872; called by muse, varscan2
- GRM3 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 84/178 reads (47%) | called by muse, varscan2
- ZXDB | c.519C>A p.N173K | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, varscan2
